Gene-level copy-number profile of tumor specimen TCGA-A7-A0DC-01B from TCGA case TCGA-A7-A0DC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.8 years (23,294 days).
Specimen TCGA-A7-A0DC-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e781547e-415c-4656-b656-c1df8cc22fc3.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A0DC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate.
https://portal.gdc.cancer.gov/files/215719cf-a02b-485c-9534-d99f663ec6dd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 545; copy number 1: 3,736; copy number 2: 49,857; copy number 3: 3,312; copy number 4: 2,756; copy number 5: 53; copy number 6: 3; copy number 7: 2; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,838,523–33,840,140, 1 gene: HSPD1P14.
- chr5:180,945,756–181,006,727, 5 genes (within-gene range 0–2): RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr10:78,352,597–78,356,100, 1 gene (within-gene range 0–17): AC010163.2.
- chr17:18,450,244–18,551,705, 9 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.
- chr21:45,974,489–46,072,248, 6 genes: AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 60 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:112,148,742–119,325,265, 47 genes, copy number 5: RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ.
- chr9:95,506,235–95,507,636, 1 gene, copy number 5: AL161729.1.
- chr10:118,004,916–118,046,941, 2 genes, copy number 6: RAB11FIP2, AC022395.1.
- chr11:72,584,572–72,621,827, 3 genes, copy number 9: PDE2A-AS2, MIR139, RNU7-105P.
- chr12:64,920,845–64,982,524, 2 genes, copy number 5 (within-gene range 2–5): LINC02231, RNU6ATAC42P.
- chr19:15,613,247–15,630,639, 2 genes, copy number 7: AC093072.1, CYP4F8.
- chr20:60,755,001–60,814,211, 2 genes, copy number 5: AL117372.1, AL139348.1.
- chr21:45,914,296–45,919,483, 1 gene, copy number 5: AJ239328.1.

Autosomal genes at a single copy (total copy number 1): 3,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
